HCMI case HCM-BROD-0344-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74250d5d-e275-4315-8775-589aa79c7fac

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Dead; Days to death: 781 days (2.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.2; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 73.1 years (26,701 days); AJCC staging edition: 7th; AJCC clinical stage: Stage III; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M0; Metastasis at diagnosis: No Metastasis; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 774 days (2.1 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 774 days (2.1 years).
- Days to follow up: 774 days (2.1 years); Disease response: Stable Disease; Progression or recurrence: No.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Non-Drinker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0344-C25-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0344-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
